Somatic mutation profile of tumor specimen TCGA-CJ-4923-01A (aliquot TCGA-CJ-4923-01A-01D-1429-08) from TCGA case TCGA-CJ-4923, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 63.9 years (23,353 days).
Specimen TCGA-CJ-4923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf907c30-0b0d-472f-908a-7a1a3ad86601.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4923-11A (Solid Tissue Normal), aliquot TCGA-CJ-4923-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e685dd1-d734-404c-805b-105dbd4aff48

The open-access MAF lists 63 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Frame Shift Del 8, Nonsense Mutation 4, Splice Site 1, RNA 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR6 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.164); catalogued as COSV51841026; called by muse, mutect2, varscan2
- ADO | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.072); catalogued as COSV65677707; called by muse, mutect2
- AIDA | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs544831530, COSV60662889; called by muse, mutect2
- AKAP17A | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 42/380 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100002124, COSV58308078; called by muse, mutect2, varscan2
- BAP1 | c.1876A>T p.K626* | Nonsense Mutation (SNP) | VAF 15/140 reads (11%) | catalogued as COSV56230186; called by muse, mutect2
- BIRC3 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV54814540; called by muse, mutect2
- BLM | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.462); catalogued as COSV61921451; called by muse, mutect2, varscan2
- BSX | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58004964; called by muse, mutect2
- CHRM2 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57764570; called by muse, mutect2
- CLTC | c.4476del p.N1492Kfs*34 | Frame Shift Del (DEL) | VAF 34/326 reads (10%) | catalogued as COSV52248712; called by mutect2, pindel, varscan2
- COBLL1 | c.3001T>G p.S1001A (on ENST00000392717; = p.S963A on NM_014900.5) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV52062692; called by muse, mutect2, varscan2
- COG8 | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV54741634; called by muse, mutect2, varscan2
- CPAMD8 | c.3182C>A p.T1061N (on ENST00000651564; = p.T1014N on NM_015692.5) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV71595717; called by muse, mutect2, varscan2
- DNAJC16 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV65448005; called by muse, mutect2, varscan2
- DYNC2H1 | c.12835C>G p.R4279G | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV62085485; called by muse, mutect2
- EIF2AK4 | c.3905T>C p.L1302S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55464588; called by muse, mutect2, varscan2
- EVI2B | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 84/542 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV58363288; called by muse, mutect2, varscan2
- GPR45 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV51522646; called by muse, mutect2
- IL16 | c.2246G>A p.G749E (on ENST00000302987 / NM_172217.5; = p.G48E on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs746802432, COSV57259846; called by muse, mutect2
- KALRN | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV53752030; called by muse, mutect2, varscan2
- KCNV2 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.894); catalogued as COSV66055496, COSV66055524; called by muse, mutect2
- KHK | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV53148139; called by muse, mutect2, varscan2
- LTBP3 | c.3026A>G p.K1009R | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.671); catalogued as COSV54210382; called by muse, mutect2, varscan2
- LUC7L2 | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV54923099; called by muse, mutect2
- MACROD2 | c.560C>A p.T187K | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV53940352; called by muse, mutect2, varscan2
- NRXN1 | c.2676G>C p.E892D | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV58434970; called by muse, mutect2, varscan2
- OR4B1 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV58881868; called by muse, mutect2
- OTOP1 | c.1710C>G p.D570E | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56390336; called by muse, mutect2
- PBRM1 | c.5009G>C p.R1670P (on ENST00000296302 / NM_001366071.2; = p.R1563P on NM_018313.5) | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56259959, COSV56266993; called by muse, mutect2, varscan2
- PNPLA6 | c.2083G>A p.D695N (on ENST00000414982 / NM_001166111.2; = p.D647N on NM_006702.5) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV55373149; called by muse, mutect2, varscan2
- PRPF8 | c.2653C>T p.L885F | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV59260314; called by muse, mutect2, varscan2
- RUNDC3B | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.215); catalogued as COSV56690220; called by muse, mutect2, varscan2
- SESTD1 | c.286del p.C96Vfs*3 | Frame Shift Del (DEL) | VAF 34/268 reads (13%) | catalogued as rs1200399689; called by mutect2, pindel, varscan2
- STK17B | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 22/193 reads (11%) | catalogued as COSV55827204; called by muse, mutect2, varscan2
- TBL1Y | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV60732311; called by muse, mutect2
- TOP3B | c.1241G>A p.R414K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV64116237, COSV64119372; called by muse, mutect2, varscan2
- TUBD1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs1411975764, COSV57871761; called by muse, mutect2
- VPS13B | c.1616A>C p.D539A | Missense Mutation (SNP) | VAF 114/419 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62015753; called by muse, mutect2, varscan2
- ZFR | c.1159T>A p.C387S | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54050099; called by muse, mutect2, varscan2
- ZNF184 | c.1292C>G p.S431* | Nonsense Mutation (SNP) | VAF 24/280 reads (9%) | catalogued as COSV53003066; called by muse, mutect2
- ZSWIM4 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765220980, COSV54319033, COSV99585480; called by muse, mutect2, varscan2
- ASTN2 | c.3282dup p.G1095Wfs*12 (on ENST00000313400 / NM_001365069.1; = p.G1044Wfs*12 on NM_014010.5) | Frame Shift Ins (INS) | VAF 35/306 reads (11%) | called by mutect2, pindel, varscan2
- KTN1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- NISCH | c.2763_2770del p.K921Nfs*45 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- RDH16 | c.127_136del p.K43Pfs*16 | Frame Shift Del (DEL) | VAF 27/183 reads (15%) | called by mutect2, pindel, varscan2
- SETD2 | c.3580del p.I1194Yfs*42 | Frame Shift Del (DEL) | VAF 33/276 reads (12%) | called by mutect2, pindel, varscan2
- SLC10A5 | c.100del p.I34Yfs*13 | Frame Shift Del (DEL) | VAF 24/225 reads (11%) | called by mutect2, pindel, varscan2
- TBC1D14 | c.1265_1270+1del p.X422_splice | Splice Site (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- TG | c.4285del p.H1429Tfs*20 | Frame Shift Del (DEL) | VAF 33/128 reads (26%) | called by mutect2, pindel, varscan2
- VHL | c.499del p.R167Gfs*3 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- ABCA8 | c.3105C>G p.S1035= | Silent (SNP) | VAF 57/383 reads (15%) | catalogued as COSV52193488; called by muse, mutect2, varscan2
- CRY1 | c.888C>T p.F296= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV50480988; called by muse, mutect2, varscan2
- E2F3 | c.666C>A p.T222= | Silent (SNP) | VAF 36/345 reads (10%) | catalogued as rs1380247804, COSV60895803; called by muse, mutect2, varscan2
- GPR152 | c.789C>T p.F263= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV56884887; called by muse, mutect2, varscan2
- IGDCC3 | c.1143C>T p.N381= | Silent (SNP) | VAF 30/172 reads (17%) | catalogued as COSV60076307; called by muse, mutect2, varscan2
- IRS1 | c.1209C>G p.T403= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as COSV100524135, COSV59333187; called by muse, mutect2, varscan2
- LPIN3 | c.1761T>C p.T587= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV60034991; called by muse, mutect2, varscan2
- PCDH1 | c.3606C>T p.C1202= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1441724898, COSV54610613; called by muse, mutect2, varscan2
- PYDC2 | c.87G>A p.L29= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as COSV72921233; called by muse, mutect2, varscan2
- SELENBP1 | c.555G>A p.P185= | Silent (SNP) | VAF 34/443 reads (8%) | catalogued as rs146898667, COSV64372900; called by muse, mutect2
- SYNJ2 | c.2430A>G p.K810= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1439666330, COSV62895488; called by muse, mutect2, varscan2
- DCHS2 | n.8599A>G | RNA (SNP) | VAF 33/254 reads (13%) | catalogued as rs1242347780, COSV61767571; called by muse, mutect2, varscan2
- RGS3 | c.2037+4451C>T | Intron (SNP) | VAF 38/615 reads (6%) | catalogued as COSV100465656; called by muse, mutect2
